Somatic mutation profile of tumor specimen 0DCYP4 from CCDI case PBBNBI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,163 days).
Specimen 0DCYP4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11a06538-d1e4-4f1f-b16f-fdfe06f2a0ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCYOC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386f8434-3b18-4807-9007-f484fa54afeb

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1549 | c.3789G>T p.M1263I | Missense Mutation (SNP) | VAF 188/924 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54323998; called by muse, mutect2, varscan2
- PKDREJ | c.3076G>A p.A1026T | Missense Mutation (SNP) | VAF 205/682 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs375908147; called by muse, mutect2, varscan2
- VCP | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 67/856 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100734081; called by muse, mutect2
